Somatic mutation profile of tumor specimen HCM-BROD-0002-C71-86A (aliquot HCM-BROD-0002-C71-86A-01D-A78L-36) from HCMI case HCM-BROD-0002-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Gliosarcoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.3 years (24,213 days).
Specimen HCM-BROD-0002-C71-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 749a07ad-5e32-4b6b-9fe5-1e81061703b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0002-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0002-C71-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53036d52-7b3d-436d-a0cc-8e0e2a0b7365

The open-access MAF lists 136 somatic variants for this specimen: 89 protein-altering or splice-affecting, 31 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 31, Intron 8, 3'UTR 5, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 3, RNA 2, Splice Site 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 174/177 reads (98%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 312/314 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABAT | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 56/720 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as rs778229930, COSV51622239; called by muse, mutect2
- ADGRB2 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 151/296 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99927139; called by muse, mutect2, varscan2
- BRF2 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144896527; called by muse, mutect2, varscan2
- CCN4 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs140971140; called by muse, mutect2
- CEACAM3 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 75/75 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs528553937; called by muse, mutect2, varscan2
- CNR2 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 111/223 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs201049279; called by muse, mutect2, varscan2
- DGKI | c.476C>G p.P159R | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as COSV55946895; called by muse, mutect2, varscan2
- EDAR | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 84/160 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs148212997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELFN1 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 72/305 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs1206191418; called by muse, mutect2, varscan2
- FAM186A | c.5491C>T p.P1831S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as rs1295245661, COSV100525170; called by muse, mutect2, varscan2
- FBXO25 | c.384G>A p.L128= (on ENST00000382824 / NM_183421.2; = p.L61= on NM_012173.3) | Splice Region (SNP) | VAF 40/81 reads (49%) | catalogued as rs377735335; called by muse, mutect2, varscan2
- GALNT14 | c.1120C>T p.R374W | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1422310831, COSV100203898, COSV61110516; called by muse, mutect2, varscan2
- GPR157 | c.340G>T p.G114W | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV101072565; called by muse, mutect2
- HKDC1 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.035); catalogued as rs1429930647; called by muse, mutect2, varscan2
- IL17F | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 226/454 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.537); catalogued as rs550486674, COSV60233991; called by muse, mutect2, varscan2
- IL21R | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 155/282 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs550842554, COSV100559944; called by muse, mutect2, varscan2
- KSR2 | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 137/272 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs550563327, CM1311380; called by muse, mutect2, varscan2
- LIPH | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV99956296; called by muse, mutect2, varscan2
- MEFV | c.2343C>A p.D781E | Missense Mutation (SNP) | VAF 10/350 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54825133; called by muse, mutect2
- MYH11 | c.2307C>G p.F769L | Missense Mutation (SNP) | VAF 23/623 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55561668; called by muse, mutect2
- MYO1D | c.1598G>A p.R533H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772624904, COSV100554719; called by muse, mutect2, varscan2
- NIBAN3 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 83/205 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs370043401, COSV56306942; called by muse, mutect2, varscan2
- OBSCN | c.9697C>T p.R3233C | Missense Mutation (SNP) | VAF 148/336 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs367605500; called by muse, mutect2, varscan2
- OR6A2 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 200/297 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs778988808, COSV100215782, COSV60264834; called by muse, mutect2, varscan2
- PCDH11Y | c.2569G>A p.V857I (on ENST00000400457 / NM_032973.2; = p.V846I on NM_032971.3) | Missense Mutation (SNP) | VAF 106/129 reads (82%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs777010130, COSV53075849; called by muse, mutect2, varscan2
- PRKACG | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 172/282 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370025582; called by muse, mutect2, varscan2
- PTPRQ | c.6830A>T p.Q2277L (on ENST00000616559; = p.Q2244L on NM_001145026.2) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57049635; called by muse, mutect2, varscan2
- RP1 | c.1298G>A p.S433N | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs971203515; called by muse, mutect2, varscan2
- SCIN | c.883G>A p.V295I (on ENST00000297029 / NM_001112706.3; = p.V48I on NM_033128.3) | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs543074443; called by muse, mutect2, varscan2
- SLCO1B3 | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 11/235 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV53932901, COSV53934334; called by muse, mutect2
- STK31 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs150391003; called by muse, mutect2, varscan2
- TBC1D8 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 170/347 reads (49%) | catalogued as rs747957096, COSV65210358; called by muse, mutect2, varscan2
- TENT5C | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 135/345 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs750792861, COSV65616442; called by muse, mutect2, varscan2
- TMEM43 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 189/432 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758817244; called by muse, mutect2, varscan2
- TOLLIP | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 113/175 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55136740; called by muse, mutect2, varscan2
- TRIP6 | c.892C>A p.R298S | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV52341842; called by muse, mutect2, varscan2
- TTC29 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as rs1454013515; called by muse, mutect2, varscan2
- TTN | c.37478G>A p.R12493Q (on ENST00000591111; = p.R5069Q on NM_003319.4) | Missense Mutation (SNP) | VAF 108/225 reads (48%) | PolyPhen benign (0.001); catalogued as rs764083952, COSV59943321; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WHRN | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 36/438 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs766869083, COSV54331100; called by muse, mutect2
- ZFAND5 | c.554A>G p.N185S | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.114); catalogued as COSV99428445; called by muse, mutect2, varscan2
- ACTR2 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- ADAM22 | c.2320del p.Y774Mfs*2 | Frame Shift Del (DEL) | VAF 23/136 reads (17%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.1779A>T p.K593N (on ENST00000611781; = p.K537N on NM_052997.2) | Missense Mutation (SNP) | VAF 103/176 reads (59%) | SIFT tolerated (0.52); PolyPhen benign (0.05); called by muse, varscan2
- BAHCC1 | c.5018G>A p.G1673E | Missense Mutation (SNP) | VAF 22/425 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2
- BLVRA | c.529G>T p.V177F | Missense Mutation (SNP) | VAF 105/720 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CHD7 | c.7698dup p.T2567Hfs*9 | Frame Shift Ins (INS) | VAF 47/225 reads (21%) | called by mutect2, pindel, varscan2
- CPA4 | c.357C>G p.N119K | Missense Mutation (SNP) | VAF 13/428 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); called by muse, mutect2
- CTSV | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CUL2 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2
- CYP4X1 | c.705C>G p.D235E | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- DCDC1 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 80/147 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DEK | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 65/132 reads (49%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- DST | c.8906T>C p.L2969P | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- DYRK1B | c.377_378dup p.K127* | Frame Shift Ins (INS) | VAF 4/47 reads (9%) | called by mutect2, pindel
- EPHX4 | c.1084del p.D362Ifs*12 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, varscan2
- ERLEC1 | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 130/279 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- EVC2 | c.1867del p.L623Sfs*38 | Frame Shift Del (DEL) | VAF 105/275 reads (38%) | called by mutect2, pindel, varscan2
- FYCO1 | c.254A>G p.N85S | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.674); called by muse, mutect2
- GALNT13 | c.884T>A p.F295Y | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GPI | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HSP90AA1 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); called by muse, mutect2
- KIF26A | c.1436T>A p.M479K | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KLHL14 | c.556T>C p.Y186H | Missense Mutation (SNP) | VAF 19/452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- MAEL | c.713A>T p.Q238L | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.073); called by muse, mutect2
- MIDEAS | c.2588C>A p.T863N | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- MSL3 | c.645del p.K215Nfs*26 (on ENST00000312196 / NM_078629.4; = p.K49Nfs*26 on NM_006800.4) | Frame Shift Del (DEL) | VAF 58/58 reads (100%) | called by mutect2, pindel*, varscan2
- NDE1 | c.928C>A p.P310T (on ENST00000577101; = p.S282Y on NM_017668.3) | Missense Mutation (SNP) | VAF 16/393 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.9); called by muse, mutect2
- NOP58 | c.292A>G p.I98V | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- NPAT | c.2934C>A p.C978* | Nonsense Mutation (SNP) | VAF 28/342 reads (8%) | called by muse, mutect2
- PIGR | c.2140+1G>T p.X714_splice | Splice Site (SNP) | VAF 52/184 reads (28%) | called by muse, mutect2, varscan2
- PLG | c.2146C>A p.L716I | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POT1 | c.891G>C p.L297F | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2
- PRAMEF7 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 238/241 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- PTPN23 | c.3578_3579insA p.V1194Cfs*12 | Frame Shift Ins (INS) | VAF 92/223 reads (41%) | called by mutect2, pindel, varscan2
- RAET1L | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- RFTN1 | c.868C>G p.Q290E | Missense Mutation (SNP) | VAF 111/224 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SATL1 | c.787G>T p.V263F (on ENST00000395409; = p.V450F on NM_001012980.2) | Missense Mutation (SNP) | VAF 189/189 reads (100%) | SIFT tolerated (0.7); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- SI | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.277); called by muse, mutect2
- SKOR2 | c.239T>A p.I80N | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC45A2 | c.728C>G p.T243R | Missense Mutation (SNP) | VAF 210/453 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYNE2 | c.16478A>T p.E5493V | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- TCF7L2 | c.1699C>T p.L567F (on ENST00000355995 / NM_001367943.1; = p.L544F on NM_030756.5) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRPV6 | c.1591A>C p.M531L | Missense Mutation (SNP) | VAF 137/601 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TWIST1 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.221); called by muse, varscan2
- ZFP92 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 166/166 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ZNF735 | c.1100C>A p.T367N | Missense Mutation (SNP) | VAF 117/600 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF816 | c.1308T>A p.S436R | Missense Mutation (SNP) | VAF 58/101 reads (57%) | SIFT tolerated (0.61); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABCC12 | c.4054T>C p.L1352= | Silent (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- ACSM5 | c.1101C>T p.Y367= | Silent (SNP) | VAF 202/417 reads (48%) | catalogued as rs369835056; called by muse, mutect2, varscan2
- ADCY4 | c.531C>T p.N177= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as rs376126420; called by muse, mutect2, varscan2
- ANK1 | c.936G>A p.A312= | Silent (SNP) | VAF 23/532 reads (4%) | catalogued as rs545633406; called by muse, mutect2
- ASMT | c.135C>T p.D45= | Silent (SNP) | VAF 44/403 reads (11%) | catalogued as rs202194252; called by muse, mutect2, varscan2
- CC2D2A | c.1656T>A p.I552= | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- CCSER1 | c.1008A>G p.S336= | Silent (SNP) | VAF 19/225 reads (8%) | catalogued as rs748326746; called by muse, mutect2
- COL1A1 | c.4056G>A p.L1352= | Silent (SNP) | VAF 173/331 reads (52%) | called by muse, mutect2, varscan2
- DACT1 | c.1716C>T p.G572= | Silent (SNP) | VAF 9/181 reads (5%) | called by muse, mutect2
- DGCR6L | c.15G>C p.A5= | Silent (SNP) | VAF 19/261 reads (7%) | called by muse, mutect2
- DLK1 | c.1014C>A p.R338= | Silent (SNP) | VAF 71/159 reads (45%) | called by muse, mutect2, varscan2
- ECE2 | c.177G>A p.T59= | Silent (SNP) | VAF 74/163 reads (45%) | called by muse, mutect2, varscan2
- ERCC6 | c.2901C>T p.T967= | Silent (SNP) | VAF 205/325 reads (63%) | called by muse, mutect2, varscan2
- FAM124B | c.1140C>T p.G380= | Silent (SNP) | VAF 166/305 reads (54%) | catalogued as rs375635395; called by muse, mutect2, varscan2
- FBXL4 | c.315T>C p.D105= | Silent (SNP) | VAF 38/168 reads (23%) | called by muse, mutect2, varscan2
- IFT172 | c.4731C>T p.F1577= | Silent (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- KRT14 | c.144C>T p.G48= | Silent (SNP) | VAF 80/159 reads (50%) | catalogued as rs1254536871, COSV51421894; called by muse, mutect2, varscan2
- LRP2 | c.9774G>A p.K3258= | Silent (SNP) | VAF 12/185 reads (6%) | called by muse, mutect2
- MAGEL2 | c.2625C>T p.S875= | Silent (SNP) | VAF 11/186 reads (6%) | catalogued as rs1204239959, COSV100046235; called by muse, mutect2
- MYH11 | c.549G>C p.G183= | Silent (SNP) | VAF 24/708 reads (3%) | called by muse, mutect2
- NLRC3 | c.921C>A p.A307= | Silent (SNP) | VAF 15/211 reads (7%) | catalogued as COSV57087294; called by muse, mutect2
- NLRP7 | c.792G>A p.A264= | Silent (SNP) | VAF 122/122 reads (100%) | catalogued as rs141553552; called by muse, mutect2, varscan2
- OR6C4 | c.270C>A p.I90= | Silent (SNP) | VAF 15/216 reads (7%) | called by muse, mutect2
- OTOG | c.1774C>T p.L592= | Silent (SNP) | VAF 14/362 reads (4%) | called by muse, mutect2
- PALM2AKAP2 | c.1428C>T p.D476= (on ENST00000259318 / NM_001136562.3; = p.D707= on NM_007203.5) | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as rs552999944; called by muse, mutect2, varscan2
- PBX4 | c.501G>A p.R167= | Silent (SNP) | VAF 60/174 reads (34%) | called by muse, mutect2, varscan2
- SNED1 | c.3603C>T p.G1201= | Silent (SNP) | VAF 158/324 reads (49%) | catalogued as rs369849516; called by muse, varscan2
- SYDE1 | c.1911C>T p.P637= | Silent (SNP) | VAF 126/236 reads (53%) | called by muse, mutect2, varscan2
- TJP2 | c.1044C>T p.D348= | Silent (SNP) | VAF 119/196 reads (61%) | catalogued as rs750420311; called by muse, mutect2, varscan2
- USH2A | c.13434A>G p.E4478= | Silent (SNP) | VAF 123/291 reads (42%) | called by muse, mutect2, varscan2
- WDR13 | c.483G>A p.A161= | Silent (SNP) | VAF 128/128 reads (100%) | catalogued as rs1009484702; called by muse, mutect2, varscan2
- AMPD3 | c.*2T>C | 3'UTR (SNP) | VAF 130/320 reads (41%) | called by muse, mutect2, varscan2
- ARHGAP23P1 | chr16:33938568 G>T | 5'Flank (SNP) | VAF 44/207 reads (21%) | called by muse, mutect2, varscan2
- C2orf83 | n.278-1361G>T | Intron (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- EML3 | c.2487+28G>T | Intron (SNP) | VAF 46/157 reads (29%) | called by muse, mutect2, varscan2
- FAM205BP | n.1814C>T | RNA (SNP) | VAF 68/945 reads (7%) | called by muse, mutect2
- FAM227B | c.1013-24889G>A | Intron (SNP) | VAF 15/15 reads (100%) | catalogued as rs555267524; called by muse, mutect2, varscan2
- FAS | c.*1303C>A | 3'UTR (SNP) | VAF 33/33 reads (100%) | called by muse, mutect2, varscan2
- KRT14 | c.1322-25C>G | Intron (SNP) | VAF 68/134 reads (51%) | called by muse, mutect2
- LYNX1-SLURP2 | c.*202C>A | 3'UTR (SNP) | VAF 80/171 reads (47%) | called by muse, mutect2, varscan2
- NKD2 | c.*44C>T | 3'UTR (SNP) | VAF 184/370 reads (50%) | catalogued as rs762186974; called by muse, varscan2
- NOD1 | c.2286-32A>G | Intron (SNP) | VAF 41/283 reads (14%) | called by muse, mutect2, varscan2
- NPIPP1 | n.914C>G | RNA (SNP) | VAF 386/842 reads (46%) | catalogued as rs759043989, COSV100722054; called by muse, mutect2, varscan2
- PHGDH | c.356+1413A>G | Intron (SNP) | VAF 149/460 reads (32%) | called by muse, mutect2, varscan2
- PRAME | c.22-1824T>C | Intron (SNP) | VAF 11/253 reads (4%) | called by muse, mutect2
- RAB18 | c.*2368G>C | 3'UTR (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- SMARCAL1 | c.1711-326G>A | Intron (SNP) | VAF 31/59 reads (53%) | catalogued as rs1326414347, COSV61924553; called by muse, mutect2, varscan2
